Somatic mutation profile of tumor specimen 0DHDZX from CCDI case PBBUBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.8 years (7,596 days).
Specimen 0DHDZX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97723df6-08e3-44f1-8290-81589843f35a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZ8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b85fffd7-f92f-40f8-b9bc-4440670a4c11

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 5, Missense Mutation 5, Silent 4, Intron 3, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNT8 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 299/671 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs149118193, COSV99362905; called by muse, mutect2, varscan2
- HS3ST1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 228/479 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50028055; called by muse, mutect2, varscan2
- NEK11 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 32/1163 reads (3%) | catalogued as rs900688268, COSV63583729; called by muse, mutect2
- SPAG6 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 369/836 reads (44%) | catalogued as rs779459381, COSV57619778; called by muse, mutect2, varscan2
- SUFU | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 217/460 reads (47%) | catalogued as CM125398, COSV64016551; called by muse, mutect2, varscan2
- ZNF76 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 289/592 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1358535831, COSV57592084; called by muse, mutect2, varscan2
- DDX3X | c.1043C>T p.A348V (on ENST00000399959; = p.A349V on NM_001356.5) | Missense Mutation (SNP) | VAF 299/309 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- LHX1 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 198/426 reads (46%) | called by muse, mutect2, varscan2
- MMP11 | c.196_201del p.Q66_E67del | In Frame Del (DEL) | VAF 102/254 reads (40%) | called by mutect2, varscan2
- MORC3 | c.1420T>G p.F474V | Missense Mutation (SNP) | VAF 226/508 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PPP4R3A | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 223/513 reads (43%) | called by muse, mutect2, varscan2
- PTCH1 | c.260dup p.L87Ffs*3 | Frame Shift Ins (INS) | VAF 506/542 reads (93%) | called by mutect2, varscan2
- ABCA12 | c.1443C>T p.T481= (on ENST00000272895 / NM_173076.3; = p.T163= on NM_015657.3) | Silent (SNP) | VAF 329/749 reads (44%) | catalogued as rs143605938, COSV55964344; called by muse, mutect2, varscan2
- ATP13A2 | c.1896G>A p.S632= | Silent (SNP) | VAF 158/352 reads (45%) | catalogued as rs575694238, COSV100454225; called by muse, mutect2, varscan2
- SLC5A6 | c.369C>T p.R123= | Silent (SNP) | VAF 274/630 reads (43%) | called by muse, mutect2, varscan2
- TLR2 | c.669C>T p.S223= | Silent (SNP) | VAF 342/800 reads (43%) | catalogued as rs776817219, COSV52604868; called by muse, mutect2, varscan2
- AC099782.1 | n.74+1936del | Intron (DEL) | VAF 324/723 reads (45%) | catalogued as COSV101417379; called by mutect2, varscan2
- CT55 | c.-51G>A | 5'UTR (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- GREB1 | c.1160-1288G>A | Intron (SNP) | VAF 160/353 reads (45%) | catalogued as rs745424155; called by muse, mutect2, varscan2
- PTPRO | c.1106-78dup | Intron (INS) | VAF 42/101 reads (42%) | catalogued as rs989392139; called by mutect2, varscan2
